Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5982, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5982-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "LEFT KIDNEY":

RENAL CELL CARCINOMA, clear cell type (3.7 cm), Fuhrman nuclear grade II/IV, present in the mid to upper pole.
Tumor is confined to the kidney and does not invade the perinephric fat.
No lymphovascular invasion present.
Ureter, renal artery, and renal vein margins are negative for tumor.
Renal cortical cyst (0.3 cm).
Non-neoplastic kidney will be assessed by the Renal Pathology Service and reported in an addendum.

AJCC Classification (6th Edition): pT1a Nx MX.

CLINICAL DATA:

History: Enhancing 4.5 cm left renal mass.
Operation: None given.
Operative Findings: None given.
Clinical Diagnosis: None given.

TISSUE SUBMITTED:

A/#1. Left kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the [REDACTED], unit number, and "#1. left kidney", and consists of a 225.5 gram left radical nephrectomy specimen (10.2 x 5.1 x 4.4 cm) with surrounding perirenal adipose tissue (0.1 to 1.1 cm in maximal thickness). Extending from the hilum is the ureter (1.6 cm in length x 0.3 cm in diameter), renal artery (1.4 cm in length x 0.2 cm in diameter) and two renal veins (each 2.1 cm in length x 0.5 cm in diameter). In the mid to upper pole, there is a 3.7 cm x 3.4 x 3.3 cm well circumscribed, golden yellow to focally hemorrhagic tumor mass. The tumor grossly abuts the renal capsule but does not appear to invade into the perirenal fat. The tumor is present 4.3 cm from the renal vein margin, and does not grossly involve the vein. The tumor is grossly 0.1 cm from the overlying fascial margin. The remaining kidney is tan/brown and unremarkable, with a well defined cortical medullary junction. The surrounding fat is thinly sectioned, and no lymph nodes or adrenal gland are identified. Representative sections of the tumor were submitted for cytogenetics and the tumor bank (T1). Representative sections of the normal were submitted for electron microscopy and immunofluorescence. Gross photographs are taken. Representative sections are submitted for microscopic examination.

MICRO A1: Renal artery, renal vein, and ureter margins, 4 frags, [REDACTED]
MICRO A2: Quick fix section (T1), 1 frag, ESS.
MICRO A3: Tumor to capsule and fascial margin, 1 frag, [REDACTED]
MICRO A4: Tumor to capsule and adjacent kidney, 1 frag, [REDACTED]
MICRO A5: Tumor with hemorrhage, 1 frag, [REDACTED]
MICRO A6: Renal parenchyma with 0.3 cm cyst, 1 frag, [REDACTED]
MICRO A7: Non-neoplastic kidney, 1 frag, [REDACTED]

[REDACTED]

[page 2 of 4]
EVALUATION OF NON-NEOPLASTIC PARENCHYMA

LEFT KIDNEY (NEPHRECTOMY SPECIMEN)

ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE (SEE NOTE)

NOTE:

The non-neoplastic parenchyma shows minor, non-specific glomerular alterations, with mild mesangial expansion and isolated double contours. Arteries and arterioles show moderately severe subintimal sclerosis. There is minimal tubular atrophy and interstitial fibrosis present.

MICROSCOPIC DESCRIPTION:

The representative section of non-neoplastic parenchyma consists of kidney cortex and medulla. There are over 200 glomeruli present in the sample submitted for light microscopy. Less than 1% of glomeruli are globally sclerosed. The preserved glomeruli show normal cellularity and only mild mesangial expansion. On PAS and [REDACTED] silver methenamine stains, the glomerular basement membranes appear of normal thickness. Isolated double contours are present in some glomeruli. Tubules are well preserved. The interstitium shows minimal fibrosis or active inflammation. Approximately 1% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries and arterioles show moderately severe subintimal sclerosis.

[REDACTED]

[page 3 of 4]
7

██████████: 45,XX,der(3)t(3;6)(p13;p11.2),-6

METAPHASES COUNTED: 5 ANALYZED: 5 SCORED: 0 BANDING: GTG

INTERPRETATION:

All metaphases contained clonal aberrations which included deletion of the chromosome 3 short arm (3p). 3p deletion is a characteristic finding in clear-cell renal cell carcinoma.

COMMENTS:

INDICATION FOR TEST:
RCC

CLINICAL DATA:
██████████

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4ec754b5-1061-4244-93ec-66ead3d36310 (TCGA-CZ-5982.DEE1C514-BA95-4B69-BD06-749A81F0CDA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).